MMRF case MMRF_1642 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/996ba5d0-c148-4f2b-9551-cbb746ad7322

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 72 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.5 years (23,930 days); ISS stage: III; Days to last known disease status: 72 days; Days to last follow up: 72 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.

Follow-up (2 entries)
- Days to follow up: -18 days; ECOG performance status: 0.
- Follow-up contact recording only the day: day 72.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- M Protein 0.71 g/dL.
- C-Reactive Protein 1.26 mg/dL.
- Immunoglobulin A 8.86 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 69.1 mg/dL.
- Total Protein 6.6 g/dL.
- Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL.
- Creatinine 150 µmol/L.
- Immunoglobulin M 0.22 g/L.
- Leukocytes 8.96 ×10⁹/L.
- Absolute Neutrophil 4.5 ×10⁹/L.
- Immunoglobulin G 3.71 g/L.
- Beta 2 Microglobulin 9.9 µg/mL.
- Platelets 336 ×10⁹/L.
- Hemoglobin 5.95 mmol/L.
- Albumin 40 g/L.
- Calcium 2.2 mmol/L.
- Lactate Dehydrogenase 2.45 µkat/L.

Other clinical attributes
- Day -18: Weight: 74 kg; Height: 161 cm.

Biospecimens (2 samples)
- Sample MMRF_1642_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_1642_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
